Gene-level copy-number profile of tumor specimen TCGA-44-8119-01A from TCGA case TCGA-44-8119, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 73.9 years (27,003 days).
Specimen TCGA-44-8119-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.d555de36-66a4-40fb-8c0a-3232a569b94a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-44-8119-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/68ba89c8-cbed-4d6b-9c57-42be58a03600

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 24; copy number 2: 2,758; copy number 3: 8,938; copy number 4: 21,923; copy number 5: 10,318; copy number 6: 5,134; copy number 7: 7,327; copy number 8: 1,127; copy number 9: 135; copy number 10: 73; copy number 11: 1,946; copy number 12: 26; copy number 13: 14; copy number 15: 9; copy number 21: 20; copy number 30: 22; copy number 45: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-44-8119-01A-11D-2237-01): tumor purity 0.55, ploidy 4.63, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:25,434,324–25,520,854, 6 genes (within-gene range 0–4): AL022324.3, AL008721.1, IGLVIVOR22-1, CRYBB2P1, MIR6817, AL008721.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,257 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:129,611,720–134,066,589, 83 genes, copy number 11 (within-gene range 4–11) (broad region; genes not listed).
- chr8:375,931–738,106, 7 genes, copy number 10: FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1.
- chr8:738,548–893,112, 2 genes, copy number 10: AC100797.4, AC026950.2.
- chr8:41,929,479–55,542,054, 195 genes, copy number 11 (within-gene range 6–11) (broad region; genes not listed).
- chr8:55,696,424–145,066,685, 1,394 genes, copy number 11–12 (within-gene range 11–23) (broad region; genes not listed).
- chr11:125,063,302–127,657,877, 64 genes, copy number 10 (broad region; genes not listed).
- chr12:389,273–684,127, 8 genes, copy number 12: CCDC77, B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455.
- chr12:1,660,315–2,004,535, 11 genes, copy number 13: MIR3649, ADIPOR2, AC005183.1, AC005343.4, RPS4XP14, CACNA2D4, AC005343.7, LRTM2, AC005342.2, LINC00940, DCP1B.
- chr12:2,004,666–2,049,463, 3 genes, copy number 13: AC005342.1, CACNA1C-IT1, CACNA1C-IT2.
- chr14:20,870,278–20,892,348, 3 genes, copy number 9: AL133371.3, AL133371.1, RNASE3.
- chr14:21,476,597–22,190,713, 64 genes, copy number 9–21 (within-gene range 4–21) (broad region; genes not listed).
- chr14:22,202,583–22,227,254, 4 genes, copy number 21: TRAV26-2, TRAV34, TRAV35, TRAV36DV7.
- chr14:31,100,112–32,837,684, 34 genes, copy number 9 (within-gene range 5–9): HECTD1, RPL21P5, RNU6-541P, Y_RNA, AL136418.1, Y_RNA, HEATR5A, ATP5MC1P2, AL139353.1, AL139353.2, DTD2, AL163973.1, GPR33, NUBPL, AL163973.3, AL163973.2, RNU6-602P, RNU6-455P, AL355112.1, LINC02313, AL352984.2, AL352984.1, ARHGAP5-AS1, ARHGAP5, AL161665.1, AL161665.2, RNU6-7, RNU6-8, AL136298.2, KIAA1143P1, AKAP6, AL136298.1, RN7SL660P, MTCO1P2.
- chr14:34,432,788–38,256,093, 93 genes, copy number 9–45 (within-gene range 5–45) (broad region; genes not listed).
- chr18:39,016,047–39,034,110, 2 genes, copy number 12: RN7SKP182, RNU6-706P.
- chr20:52,972,358–64,313,132, 290 genes, copy number 11 (within-gene range 7–11) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 24. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
